CCDI case PBCHKD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/09094ef4-bffd-43f4-bdf9-f22d86b2d182

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 3.3 years (1,221 days).

Biospecimens (3 samples)
- Sample 0DSZSF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSZSI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DSZSJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
